Gene-level copy-number profile of tumor specimen TCGA-FP-8631-01A from TCGA case TCGA-FP-8631, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 68.2 years (24,898 days).
Specimen TCGA-FP-8631-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.740f41e0-4e17-4dd1-9c9f-cc1a7609b915.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FP-8631-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/812d9534-1b7d-414b-980f-e4a988b189de

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 539; copy number 2: 22,603; copy number 3: 20,105; copy number 4: 7,728; copy number 5: 5,086; copy number 6: 2,104; copy number 7: 489; copy number 8: 416; copy number 9: 214; copy number 10: 36; copy number 11: 9; copy number 12: 82; copy number 13: 73; copy number 14: 7; copy number 17: 24; copy number 19: 46; copy number 20: 114; copy number 21: 2; copy number 22: 16; copy number 23: 32; copy number 25: 4; copy number 30: 3; copy number 32: 33; copy number 37: 29; copy number 48: 10; copy number 69: 11.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FP-8631-01A-11D-2390-01): tumor purity 0.58, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,840 genes in 54 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–169,103,276, 993 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr1:193,304,745–199,393,307, 58 genes, copy number 5–7: LINC01031, AL138778.1, AL136456.1, AL357793.1, AL357793.2, RPL23AP22, EEF1A1P14, AL513348.1, RNU6-983P, AL353072.1, AL353072.2, AL353709.1, LINC01724, KCNT2, MIR4735, CFH, CFHR3, CFHR1, BX248415.1, CFHR4, CFHR2, AL139418.1, CFHR5, F13B, ASPM, SEPTIN14P12, ZBTB41, AL513325.1, CRB1, MRPS21P3, AL136322.1, DENND1B, Y_RNA, EEF1A1P32, AL365258.2, FAM204BP, AL365258.1, C1orf53, LHX9, NEK7, PRR13P1, AL450352.1, ATP6V1G3, AL157402.1, PTPRC, AL157402.2, PEBP1P3, MIR181A1HG, MIR181B1, MIR181A1, AC096631.2, AC096631.1, LINC01222, LINC01221, AC105941.1, LINC02789, RPL23AP16, AC099335.1.
- chr1:205,657,851–207,386,804, 58 genes, copy number 6 (within-gene range 4–6): SLC45A3, Metazoa_SRP, NUCKS1, SNORA72, RAB29, AC119673.1, SLC41A1, AC119673.2, PM20D1, SLC26A9, AL713965.1, RAB7B, CTSE, BX571818.1, RHEX, AC244035.3, AVPR1B, AC244035.1, AC244035.4, RPL22P4, AC244035.2, FAM72A, SRGAP2, AC244023.1, IKBKE, MIR6769B, C1orf147, AC244034.2, RASSF5, AC244034.1, AC244034.3, EIF2D, DYRK3-AS1, DYRK3, MAPKAPK2, AL591846.1, Y_RNA, IL10, IL19, IL20, IL24, FCMR, AC098935.2, AC098935.1, PIGR, FCAMR, C1orf116, PFKFB2, YOD1, C4BPB, C4BPA, AL445493.3, AL445493.1, C4BPAP1, AL445493.2, C4BPAP2, AL596218.1, CD55.
- chr1:234,669,523–246,507,312, 204 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:246,321,663–248,919,946, 131 genes, copy number 5 (broad region; genes not listed).
- chr2:46,698,940–49,595,126, 55 genes, copy number 5: LINC01118, SOCS5, LINC01119, AC016722.1, AC016722.2, MCFD2, TTC7A, AC093732.2, AC093732.1, STPG4, AC073283.3, AC073283.1, CALM2, EPCAM-DT, AC073283.2, BCYRN1, EPCAM, RN7SKP119, MIR559, Metazoa_SRP, MSH2, KCNK12, MSH2-OT1, AC079250.1, MSH6, NME2P2, AC006509.1, U6, FBXO11, RPL36AP15, RPS27AP7, AC079807.1, AC092650.1, PPIAP62, VN1R18P, RN7SKP224, FOXN2, RNU4-49P, AC093635.1, PPP1R21, RNU6-282P, STON1, STON1-GTF2A1L, GTF2A1L, AC073082.1, TPT1P11, LHCGR, ELOBP3, AC009975.1, CTBP2P5, FSHR, MIR548BA, AC009975.2, RNU6-439P, AC009971.1.
- chr2:102,311,502–102,736,888, 10 genes, copy number 5 (within-gene range 3–5): IL1RL1, IL18R1, SDR42E1P5, IL18RAP, MIR4772, AC007278.2, AC007278.1, SLC9A4, SLC9A2, MFSD9.
- chr2:177,623,244–180,007,297, 41 genes, copy number 5 (within-gene range 3–5): PDE11A, PDE11A, PDE11A-AS1, AC011998.2, API5P2, SDHDP5, RNU6-629P, CYCTP, AC011998.1, RBM45, RNU5E-9P, OSBPL6, CHROMR, PRKRA, PJVK, NUDCP2, FKBP7, PLEKHA3, TTN-AS1, TTN, AC009948.2, AC009948.1, AC009948.3, AC010680.3, AC010680.2, AC010680.4, AC010680.5, AC010680.1, AC092640.1, CCDC141, RNU7-104P, RPS6P2, SESTD1, AC093911.1, RAD52P1, ZNF385B, TXNL4AP1, MIR1258, AC096587.2, AC096587.1, CWC22.
- chr3:131,533,555–184,780,720, 846 genes, copy number 5–10 (broad region; genes not listed).
- chr3:185,506,262–198,222,513, 290 genes, copy number 5–11 (within-gene range 1–11) (broad region; genes not listed).
- chr5:25,963,839–27,496,994, 13 genes, copy number 5: AC113370.1, RNU4-43P, AC025475.1, AC025475.2, AC113347.1, AC113347.2, AC113347.3, AC113347.4, CCNB3P1, CDH9, RNU6-738P, PURPL, AC113355.1.
- chr6:30,839,526–31,673,546, 85 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr6:32,812,763–56,954,649, 559 genes, copy number 5–10 (broad region; genes not listed).
- chr7:70,972–14,071,380, 253 genes, copy number 7–11 (broad region; genes not listed).
- chr7:16,849,957–30,179,014, 248 genes, copy number 7–9 (broad region; genes not listed).
- chr7:43,274,159–62,275,678, 329 genes, copy number 5–8 (broad region; genes not listed).
- chr7:86,643,914–94,431,227, 115 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr7:94,656,325–108,995,029, 371 genes, copy number 7–19 (broad region; genes not listed).
- chr7:111,726,110–118,513,830, 102 genes, copy number 5–21 (broad region; genes not listed).
- chr8:43,542,076–130,017,129, 1,239 genes, copy number 6–8 (broad region; genes not listed).
- chr8:131,432,776–141,786,313, 116 genes, copy number 6 (broad region; genes not listed).
- chr8:142,198,356–145,066,685, 166 genes, copy number 5 (broad region; genes not listed).
- chr10:68,331,174–68,700,794, 13 genes, copy number 17: HNRNPH3, RUFY2, DNA2, RPL26P29, RNA5SP319, SLC25A16, RPL26P27, Y_RNA, TMEM14DP, TET1, COX20P1, RPS3AP37, AL513534.2.
- chr10:71,319,259–76,560,994, 145 genes, copy number 6–20 (broad region; genes not listed).
- chr10:81,870,778–83,912,922, 13 genes, copy number 22–48: AL096706.1, NRG3, AC010157.2, AC010157.1, NRG3-AS1, RNU6-441P, RNU6-478P, MARK2P15, LINC02650, AC069540.2, AC069540.1, RNU6-129P, AL390786.1.
- chr12:38,078,529–38,329,721, 11 genes, copy number 69: AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B.
- chr12:52,729,517–53,293,638, 36 genes, copy number 5 (within-gene range 3–5): KRT125P, AC055716.2, AC055716.1, BTBD10P1, KRT127P, ARL2BPP2, KRT76, AC107016.2, KRT3, KRT4, KRT79, AC107016.1, KRT78, RPL7P41, KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3, IGFBP6, SOAT2, VTI1BP3, RNU6-333P, HIGD1AP1, EIF4A1P4, CSAD, AC073573.1, ZNF740, ITGB7, RARG, AC021072.1, MFSD5, ESPL1.
- chr12:68,332,888–68,850,686, 21 genes, copy number 5: LINC02384, AC022511.1, AC008033.3, AC008033.1, AC008033.2, RPSAP12, Metazoa_SRP, RAP1B, RPL10P12, SNORA70G, ATP5PDP4, AC090061.1, RPL7P42, NUP107, KRT8P39, SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:92,247,697–92,929,331, 10 genes, copy number 6 (within-gene range 3–6): LINC02391, CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1, PLEKHG7, EEA1, AC026111.1, HNRNPA1P50.
- chr13:18,467,172–22,837,880, 122 genes, copy number 13–32 (broad region; genes not listed).
- chr13:72,703,693–73,661,891, 17 genes, copy number 5: RPL21P110, RNU6-80P, MZT1, BORA, DIS3, PIBF1, RNU6-79P, PSMD10P3, KLF5, FABP5P1, RNU6-66P, RNU4-10P, RNY1P8, AL162376.1, MARK2P12, LINC00393, LINC00392.
- chr15:92,281,484–98,420,998, 115 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr17:36,591,879–39,747,291, 114 genes, copy number 8–22 (within-gene range 3–22) (broad region; genes not listed).
- chr17:50,719,565–51,120,868, 15 genes, copy number 6 (within-gene range 3–6): LUC7L3, AC005921.3, ANKRD40CL, MIR8059, AC005921.4, AC005921.1, WFIKKN2, AC091062.1, RPL5P33, TOB1, TOB1-AS1, AC005920.4, AC005920.1, AC005920.3, SPAG9.
- chr18:47,390–5,238,598, 109 genes, copy number 5 (broad region; genes not listed).
- chr18:9,473,421–9,862,551, 16 genes, copy number 8 (within-gene range 4–8): AP005432.2, RALBP1, AP005432.1, RNU2-27P, PPP4R1, AP001381.1, PPP4R1-AS1, RNU6-903P, LINC02856, KRT18P8, RAB31, AP000902.1, ZNF415P1, RN7SL862P, AC006238.2, RNA5SP449.
- chr18:20,946,906–33,441,101, 206 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).
- chr19:29,083,094–31,349,436, 38 genes, copy number 37–48: AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1, AC011507.1, LINC01834, AC020897.1, AC020912.1, TSHZ3, LINC01791.
- chr20:12,865,202–64,313,132, 1,193 genes, copy number 5–7 (broad region; genes not listed).
- chr21:35,136,638–46,665,124, 333 genes, copy number 5–8 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 539. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
